Somatic mutation profile of tumor specimen TCGA-EY-A1GK-01A (aliquot TCGA-EY-A1GK-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.3 years (27,127 days).
Specimen TCGA-EY-A1GK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da1b652c-397a-4a85-b478-f6b8f5fe68d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GK-10A (Blood Derived Normal), aliquot TCGA-EY-A1GK-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/907dcea3-ba17-4cd9-b5a5-6a1850b8b8b0

The open-access MAF lists 1,042 somatic variants for this specimen: 782 protein-altering or splice-affecting, 225 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 475, Silent 225, Frame Shift Del 205, Frame Shift Ins 46, Nonsense Mutation 25, Splice Site 19, Intron 12, RNA 8, 3'Flank 6, In Frame Del 5, Splice Region 5, 3'UTR 4.

Variants (750 of 1,042; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 18/77 reads (23%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BCS1L | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 30/91 reads (33%) | catalogued as rs550497120, COSV99829092; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 34/104 reads (33%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- COL5A1 | c.2897del p.P966Lfs*108 | Frame Shift Del (DEL) | VAF 58/156 reads (37%) | catalogued as rs1179967153; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- MKRN3 | c.482dup p.A162Gfs*15 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1392_1403del p.D464_Y467del (on ENST00000521381 / NM_181523.3; = p.D194_Y197del on NM_181504.4) | In Frame Del (DEL) | VAF 8/27 reads (30%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 42/68 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RBM39 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53614904; called by muse, mutect2, varscan2
- VWF | c.6553C>T p.R2185W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569962285, COSV99777509; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.2843G>A p.R948Q (on ENST00000404938 / NM_001163941.2; = p.R503Q on NM_178559.6) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.178); catalogued as rs200559589, COSV51720897; called by muse, mutect2, varscan2
- AC092143.1 | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100205928; called by muse, mutect2, varscan2
- AC098582.1 | c.745T>C p.C249R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99985731; called by muse, mutect2, varscan2
- AC131160.1 | c.944T>C p.I315T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100226256; called by muse, mutect2, varscan2
- ACAD11 | c.1501A>G p.T501A | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99392238; called by muse, mutect2, varscan2
- ACBD3 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as COSV100831061; called by muse, mutect2, varscan2
- ACSL5 | c.948+2T>C p.X316_splice (on ENST00000354273; = p.X372_splice on NM_016234.3) | Splice Site (SNP) | VAF 10/71 reads (14%) | catalogued as rs1169798756, COSV100634679; called by muse, mutect2, varscan2
- ACTR3 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); catalogued as rs375240866; called by muse, mutect2, varscan2
- ADAD1 | c.244del p.I82Yfs*6 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs746068816; called by mutect2, varscan2
- ADAM12 | c.2408C>T p.P803L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100903426; called by muse, mutect2, varscan2
- ADAMTS1 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV53170705, COSV99536294; called by muse, mutect2, varscan2
- ADAMTS14 | c.2593G>A p.G865R | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV100941679, COSV64604528; called by muse, mutect2, varscan2
- ADAMTS14 | c.3548C>G p.T1183S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV100941680; called by muse, mutect2, varscan2
- ADAMTS20 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101239642; called by muse, mutect2, varscan2
- ADAMTSL2 | c.679C>A p.L227I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.863); catalogued as rs927558070, COSV100618982; called by muse, mutect2, varscan2
- ADPRHL1 | c.907+2T>C p.X303_splice | Splice Site (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100733465; called by muse, mutect2, varscan2
- ADSS1 | c.197del p.X66_splice | Splice Site (DEL) | VAF 9/36 reads (25%) | catalogued as rs760706338; called by mutect2, pindel, varscan2
- AEBP1 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as rs1166216491, COSV56256056; called by muse, mutect2, varscan2
- AGBL1 | c.3002A>C p.Q1001P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.013); catalogued as COSV101223544; called by muse, mutect2, varscan2
- AGBL5 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as COSV100549194; called by muse, mutect2, varscan2
- AGO1 | c.49dup p.L17Pfs*28 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | catalogued as rs752471592; called by mutect2, varscan2
- AGO2 | c.1375dup p.Q459Pfs*215 | Frame Shift Ins (INS) | VAF 17/52 reads (33%) | catalogued as rs1391347693; called by mutect2, pindel, varscan2
- AIF1L | c.332T>C p.M111T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV99908256; called by muse, mutect2, varscan2
- AIFM3 | c.1417del p.A474Pfs*8 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as COSV53150313; called by mutect2, pindel, varscan2
- AKAP17A | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1487755505, COSV100002334; called by muse, mutect2, varscan2
- ALDH5A1 | c.622A>G p.S208G | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); catalogued as rs748783975, COSV100708829; called by muse, mutect2, varscan2
- ALDH6A1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV100620915; called by muse, mutect2, varscan2
- ALOX5 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100980099; called by mutect2, varscan2
- AMIGO2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs778977083, COSV56973856; called by muse, mutect2, varscan2
- AMOTL1 | c.1331T>C p.M444T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as COSV100504527; called by muse, mutect2, varscan2
- ANKIB1 | c.1597A>G p.N533D | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99729371; called by muse, mutect2, varscan2
- ANKRD17 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs867473616, COSV100429501; called by muse, mutect2, varscan2
- ANKRD29 | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99409218; called by muse, mutect2, varscan2
- ANPEP | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs774575427, COSV100263219; called by muse, mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs759218332; called by mutect2, varscan2
- AP1S2 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as COSV100236791; called by muse, mutect2, varscan2
- AP3D1 | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs950628043, COSV100642796; called by muse, mutect2, varscan2
- AP5Z1 | c.2378C>T p.T793M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.02); catalogued as rs775668440, COSV100804180; called by muse, varscan2
- APOBR | c.389A>G p.Q130R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as COSV100112674; called by muse, mutect2, varscan2
- APOL5 | c.604G>C p.A202P | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99968424; called by muse, mutect2, varscan2
- ARAP3 | c.3119G>A p.R1040Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141538563; called by muse, mutect2, varscan2
- ARFGAP3 | c.896del p.N299Mfs*22 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs774441374, COSV54310368; called by mutect2, varscan2
- ARHGAP22 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs375336457; called by muse, mutect2, varscan2
- ARHGAP33 | c.3307del p.A1103Lfs*65 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as COSV50182902; called by mutect2, pindel, varscan2
- ARHGAP35 | c.2521C>A p.H841N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101351276; called by muse, mutect2, varscan2
- ARHGEF10L | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV100769962; called by muse, mutect2, varscan2
- ARHGEF16 | c.893_895del p.S298del | In Frame Del (DEL) | VAF 11/26 reads (42%) | catalogued as rs765928654; called by mutect2, pindel, varscan2
- ARHGEF4 | c.924+2T>C p.X308_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100388345; called by muse, mutect2, varscan2
- ARHGEF9 | c.792C>T p.H264= | Splice Region (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99492049; called by muse, mutect2, varscan2
- ARID2 | c.1334T>C p.M445T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100536467; called by muse, mutect2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as rs761154268; called by mutect2, varscan2
- ASPH | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.423); catalogued as COSV62858495, COSV62858754; called by muse, mutect2, varscan2
- ASPM | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs758801375, COSV99660661; called by muse, mutect2
- ATAD2 | c.3019C>T p.R1007* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV54879522; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATG2A | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.294); catalogued as rs567094825, COSV101034549; called by muse, mutect2, varscan2
- ATRIP | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.281); catalogued as COSV100202852; called by muse, mutect2, varscan2
- B4GALNT4 | c.918del p.R307Vfs*100 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as rs770737105, COSV57327371; called by mutect2, pindel, varscan2
- BAG3 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100958251; called by muse, mutect2, varscan2
- BANK1 | c.1577C>A p.P526H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.799); catalogued as rs753585763, COSV100536530; called by muse, mutect2, varscan2
- BCAN | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs574942413, COSV61256435; called by muse, mutect2, varscan2
- BCL2 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.1); catalogued as COSV100384954; called by muse, mutect2, varscan2
- BCL7A | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV99947124; called by muse, mutect2, varscan2
- BCL9 | c.3764G>T p.G1255V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99325397; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1661G>A p.S554N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100863827; called by muse, mutect2, varscan2
- BMP7 | c.620A>T p.D207V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs1000981409, COSV101216062; called by muse, mutect2, varscan2
- BOD1L1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as COSV99239762; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs763134487; called by mutect2, varscan2
- BRINP3 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66514596; called by muse, mutect2, varscan2
- BSN | c.10045G>T p.A3349S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV99608952; called by muse, mutect2, varscan2
- BUB1 | c.3227T>C p.L1076P | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100241402; called by muse, mutect2, varscan2
- C11orf80 | c.1583G>A p.S528N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV100547126; called by muse, mutect2, varscan2
- C12orf42 | c.1009del p.R337Afs*19 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs771322722; called by mutect2, pindel, varscan2
- C1QL3 | c.368C>G p.T123R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV100127032; called by muse, mutect2
- C2CD2 | c.1243A>G p.T415A | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100298241; called by muse, mutect2, varscan2
- C4A | c.3587C>T p.T1196M | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs373949324; called by muse, mutect2, varscan2
- C6orf89 | c.295T>C p.S99P (on ENST00000373685; = p.S106P on NM_152734.4) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100769742; called by muse, mutect2, varscan2
- C7orf61 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 27/44 reads (61%) | catalogued as rs535561832, COSV100190303; called by muse, mutect2, varscan2
- C9orf131 | c.2686A>C p.S896R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100398165; called by muse, mutect2, varscan2
- CABIN1 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV99573526; called by muse, mutect2, varscan2
- CACNA1D | c.5189C>T p.P1730L (on ENST00000350061 / NM_001128840.3; = p.P1750L on NM_000720.4) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV55446810, COSV99858815; called by mutect2, varscan2
- CACNA1G | c.1883C>A p.P628H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100662083; called by muse, mutect2, varscan2
- CACNA2D2 | c.2201C>T p.T734M (on ENST00000479441 / NM_001174051.3; = p.T727M on NM_006030.4) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99817956; called by muse, mutect2, varscan2
- CACNA2D3 | c.2124G>A p.W708* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as rs1553906249, COSV99874710; called by muse, mutect2, varscan2
- CAMK2A | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100804573; called by muse, mutect2, varscan2
- CAPN10 | c.911A>T p.E304V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99550356; called by muse, mutect2, varscan2
- CAPN2 | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1305823776, COSV99689036; called by muse, mutect2, varscan2
- CAPN5 | c.1228C>T p.R410* (on ENST00000456580; = p.R370* on NM_004055.5) | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as rs565629714, COSV53685453; called by muse, mutect2, varscan2
- CARD6 | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.07); catalogued as rs764329594, COSV99620953; called by muse, mutect2
- CARD9 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs1448397897, COSV99396021; called by muse, mutect2, varscan2
- CASK | c.2685C>G p.I895M (on ENST00000378163 / NM_001367721.1; = p.I890M on NM_003688.3) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV100587386; called by muse, mutect2, varscan2
- CASP3 | c.415del p.I139* | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as COSV57724692; called by pindel, varscan2
- CCBE1 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199902030; called by muse, mutect2, varscan2
- CCDC198 | c.836T>C p.V279A | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99371290; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC43 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as rs750662055, COSV59519226; called by muse, mutect2, varscan2
- CCL18 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as rs778538949; called by muse, mutect2, varscan2
- CCM2L | c.141del p.D48Tfs*27 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as COSV52949350; called by mutect2, pindel, varscan2
- CCZ1B | c.1370del p.N457Mfs*4 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs777044936; called by pindel, varscan2
- CD101 | c.2237A>G p.Q746R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99869852; called by muse, mutect2, varscan2
- CDC42 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); catalogued as COSV100212630; called by muse, mutect2, varscan2
- CDC7 | c.1180+2T>C p.X394_splice | Splice Site (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99319817; called by muse, mutect2, varscan2
- CDC73 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV100813910, COSV66467919; called by muse, mutect2, varscan2
- CDH10 | c.2054del p.K685Sfs*34 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs1561116064; called by mutect2, pindel, varscan2
- CDH18 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.222); catalogued as COSV56975467; called by muse, mutect2, varscan2
- CDH20 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as COSV53004433; called by muse, mutect2, varscan2
- CDH7 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs146054448, COSV100542177, COSV100542376; called by muse, mutect2, varscan2
- CDK12 | c.3871del p.Q1291Rfs*3 (on ENST00000447079 / NM_016507.4; = p.Q1282Rfs*3 on NM_015083.3) | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as COSV71000053; called by mutect2, pindel, varscan2
- CECR2 | c.3584G>A p.R1195Q (on ENST00000342247 / NM_001290047.2; = p.R1011Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs777144786, COSV99378428; called by muse, mutect2, varscan2
- CELF2 | c.994A>G p.M332V (on ENST00000416382 / NM_001025077.3; = p.M339V on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100257816; called by muse, mutect2, varscan2
- CELSR3 | c.4988+2T>C p.X1663_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV50850245; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEPT1 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100853476; called by muse, mutect2, varscan2
- CERK | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.319); catalogued as COSV99348680; called by muse, mutect2, varscan2
- CERS2 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as rs949301986, COSV99645131; called by muse, mutect2, varscan2
- CHD4 | c.4220A>G p.Q1407R (on ENST00000357008 / NM_001363606.2; = p.Q1420R on NM_001273.5) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV100538362; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as rs1322050057; called by mutect2, pindel, varscan2
- CHD7 | c.7736G>T p.R2579M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as COSV101418316; called by muse, mutect2, varscan2
- CHD9 | c.4159A>G p.T1387A | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV99529334; called by muse, mutect2, varscan2
- CHM | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100718310; called by muse, mutect2, varscan2
- CHN1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.554); catalogued as rs1339005530, COSV99040470; called by muse, mutect2
- CHRNE | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM141593, COSV99545096; called by muse, mutect2, varscan2
- CHST2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.703); catalogued as COSV100536006; called by muse, mutect2, varscan2
- CHST4 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748043139, COSV100632883; called by muse, mutect2, varscan2
- CIITA | c.2546G>A p.G849D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.608); catalogued as COSV100162272; called by muse, mutect2, varscan2
- CLCN2 | c.1142del p.P381Lfs*35 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | catalogued as rs1217596296; called by mutect2, pindel, varscan2
- CLCN7 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99247413; called by muse, mutect2, varscan2
- CLNK | c.128T>C p.M43T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99905402; called by muse, varscan2
- CNDP1 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.49); PolyPhen probably damaging (1); catalogued as rs767889404, COSV100722202; called by muse, mutect2, varscan2
- CNOT3 | c.1270A>C p.N424H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.795); catalogued as COSV99652068; called by muse, mutect2
- COBL | c.783+2T>C p.X261_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99473127; called by muse, mutect2, varscan2
- COG1 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100245366; called by muse, mutect2, varscan2
- COL14A1 | c.2549A>G p.D850G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99919738; called by muse, mutect2, varscan2
- COL15A1 | c.2642del p.K881Rfs*36 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as COSV66641805; called by mutect2, pindel, varscan2
- COL22A1 | c.3609+2T>C p.X1203_splice | Splice Site (SNP) | VAF 15/28 reads (54%) | catalogued as rs1413788564, COSV100279106; called by muse, mutect2, varscan2
- COL4A2 | c.3776C>T p.P1259L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.186); catalogued as COSV100847400; called by muse, mutect2, varscan2
- COL4A2 | c.4850G>A p.R1617Q | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs748967769, COSV100847401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A4 | c.3472del p.D1158Ifs*10 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as COSV61629657, COSV61629917; called by mutect2, pindel, varscan2
- COL9A2 | c.1242dup p.G415Rfs*29 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs756694568; ClinVar: uncertain significance; called by mutect2, varscan2
- COLEC12 | c.1740del p.G581Afs*65 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as rs750635929, COSV68369940; called by mutect2, pindel, varscan2
- COP1 | c.1328A>G p.K443R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.931); catalogued as COSV100443517; called by muse, mutect2, varscan2
- CPSF7 | c.1118C>T p.T373I (on ENST00000394888 / NM_001136040.4; = p.T416I on NM_024811.4) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100467434; called by muse, mutect2
- CPT1A | c.1748G>A p.G583D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV99681384; called by muse, mutect2, varscan2
- CRB1 | c.3214A>G p.N1072D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV66331477; called by muse, mutect2, varscan2
- CSGALNACT1 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100175194; called by muse, mutect2, varscan2
- CSPG4 | c.5429C>T p.A1810V | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100413880; called by muse, mutect2, varscan2
- CSPG4 | c.1652A>G p.D551G | Missense Mutation (SNP) | VAF 9/282 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs939527051, COSV100413881; called by muse, mutect2
- CUEDC1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.336); catalogued as COSV100804786; called by muse, mutect2, varscan2
- CXCR4 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs1425457196, COSV99603141; called by muse, mutect2, varscan2
- CXorf66 | c.490T>A p.S164T | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.723); catalogued as COSV100983910; called by muse, mutect2
- CYB5R2 | c.433del p.T145Hfs*8 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | catalogued as rs775988957; called by mutect2, pindel, varscan2
- CYP2B6 | c.164T>C p.F55S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100137622; called by muse, mutect2, varscan2
- CYP4F12 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.154); catalogued as COSV100215916; called by muse, mutect2
- DAPK1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs755737290, COSV63789914; called by muse, mutect2, varscan2
- DAPK2 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99977525; called by muse, mutect2, varscan2
- DCAF12L1 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV64421899; called by muse, mutect2, varscan2
- DCANP1 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.222); catalogued as COSV101538259; called by muse, mutect2, varscan2
- DCDC1 | c.2078C>T p.S693L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs753311306, COSV60849793; called by muse, mutect2, varscan2
- DCLK3 | c.327del p.R110Gfs*69 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as COSV101373865, COSV69362732; called by mutect2, pindel, varscan2
- DCUN1D3 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs202156477, COSV100176932; called by muse, mutect2, varscan2
- DDIAS | c.2743G>T p.G915C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61271970; called by muse, mutect2, varscan2
- DDIT3 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100007465; called by muse, mutect2, varscan2
- DDX53 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60069795; called by muse, mutect2, varscan2
- DEGS2 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs776729713, COSV99979255; called by muse, mutect2, varscan2
- DENND2A | c.1132A>G p.M378V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749944873, COSV99326391; called by muse, mutect2, varscan2
- DEUP1 | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99977324; called by muse, mutect2, varscan2
- DHRS3 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs779115636, COSV100879645; called by muse, mutect2, varscan2
- DHX58 | c.374T>C p.F125S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99288342; called by muse, mutect2, varscan2
- DISP3 | c.3805dup p.H1269Pfs*115 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | catalogued as rs756156984; called by mutect2, varscan2
- DLX2 | c.149C>A p.P50H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV99308615; called by muse, mutect2, varscan2
- DNAH17 | c.9655C>T p.P3219S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as rs1395670853, COSV101102741; called by muse, mutect2, varscan2
- DNAH17 | c.4301C>T p.T1434I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226997702, COSV101102742; called by muse, mutect2, varscan2
- DNAH2 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.932); catalogued as rs151273416; called by muse, mutect2, varscan2
- DNAI1 | c.1753G>A p.V585M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs765035797, COSV99646948; called by muse, mutect2, varscan2
- DOCK10 | c.2071A>G p.N691D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV99290267; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK5 | c.5406C>T p.S1802= | Splice Region (SNP) | VAF 10/52 reads (19%) | catalogued as rs1351181657, COSV99377214; called by muse, mutect2, varscan2
- DPYSL3 | c.1359G>A p.M453I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100575216; called by muse, mutect2, varscan2
- DROSHA | c.2879C>T p.S960L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs757002340, COSV100757870, COSV60782435; called by muse, mutect2, varscan2
- DSCAML1 | c.2725G>A p.V909I (on ENST00000321322; = p.V849I on NM_020693.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761551361, COSV58386679; called by muse, mutect2, varscan2
- DST | c.21862G>T p.G7288C (on ENST00000361203 / NM_001374722.1; = p.G4961C on NM_015548.5) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs753485138, COSV55044919, COSV99757731; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs369293935; called by mutect2, varscan2
- ECHS1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as COSV100881916; called by muse, mutect2, varscan2
- ECI1 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100066870; called by muse, mutect2, varscan2
- EDEM3 | c.2663A>G p.Q888R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.026); catalogued as COSV100545447; called by muse, mutect2, varscan2
- EFTUD2 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV101274549; called by muse, mutect2, varscan2
- EIF3D | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV99341624; called by muse, mutect2, varscan2
- EIF4G1 | c.610T>A p.S204T (on ENST00000346169 / NM_198241.3; = p.S8T on NM_004953.5) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV100072013; called by muse, mutect2
- ELK3 | c.525dup p.V176Rfs*14 | Frame Shift Ins (INS) | VAF 12/31 reads (39%) | catalogued as rs769175197; called by mutect2, varscan2
- ENDOU | c.484G>A p.V162I (on ENST00000422538 / NM_001172439.2; = p.V121I on NM_006025.4) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs202194272, COSV57465401; called by muse, mutect2, varscan2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs35675992; called by mutect2, pindel, varscan2
- EPC1 | c.1582C>T p.H528Y | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.647); catalogued as COSV99553117; called by muse, mutect2, varscan2
- EPHB3 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755491313, COSV100382879; called by mutect2, varscan2
- ERICH3 | c.3178C>T p.R1060* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as rs748283860, COSV58616651; called by muse, mutect2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 36/52 reads (69%) | catalogued as rs775950025; called by mutect2, varscan2
- ETFB | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1402136329, COSV100495710; called by muse, mutect2, varscan2
- ETV7 | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs945221138, COSV100339250; called by muse, mutect2, varscan2
- EVC2 | c.3272G>T p.C1091F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100186292; called by muse, mutect2, varscan2
- FAM135B | c.3773G>A p.S1258N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52715634; called by muse, mutect2, varscan2
- FAM13B | c.2174G>T p.R725M | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99221539; called by muse, mutect2, varscan2
- FAM155A | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV65582507; called by muse, mutect2, varscan2
- FAM71A | c.327del p.K109Nfs*8 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | catalogued as rs749381759; called by mutect2, pindel, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FAR1 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV100701602; called by muse, mutect2, varscan2
- FAR2 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs868406660, COSV99479279; called by muse, mutect2, varscan2
- FARP1 | c.1469del p.G490Efs*7 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | catalogued as rs781296424, COSV60339953; called by mutect2, pindel, varscan2
- FASN | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100147997; called by muse, mutect2, varscan2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs772635228; called by mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as rs144178676; called by mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FKBP9 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.374); catalogued as rs530788472, COSV99639683; called by muse, mutect2, varscan2
- FLNA | c.2527dup p.A843Gfs*12 | Frame Shift Ins (INS) | VAF 31/120 reads (26%) | catalogued as rs782312089; called by mutect2, pindel, varscan2
- FOS | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1239748069, COSV100338506; called by muse, mutect2, varscan2
- FOXO3 | c.1740G>A p.M580I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.22); catalogued as COSV100669980; called by muse, mutect2, varscan2
- FOXS1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV54067040; called by muse, mutect2, varscan2
- FPGS | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1398228830, COSV100948836; called by muse, mutect2, varscan2
- FRYL | c.2039A>G p.Y680C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV99977341; called by muse, mutect2
- FSCB | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV100469487; called by muse, mutect2, varscan2
- FTSJ1 | c.98A>G p.D33G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99191423; called by muse, mutect2, varscan2
- FYCO1 | c.2443A>G p.M815V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs968264948, COSV99945874; called by muse, mutect2, varscan2
- FZD2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.652); catalogued as COSV100190599; called by muse, mutect2
- FZD5 | c.1184A>G p.Q395R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.889); catalogued as COSV99776426; called by muse, mutect2, varscan2
- GAA | c.2041-1G>A p.X681_splice | Splice Site (SNP) | VAF 7/49 reads (14%) | catalogued as rs760731229, CS083932, COSV100163348; called by muse, mutect2
- GABRA3 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1453531103, COSV100942994, COSV64798236; called by muse, mutect2, varscan2
- GABRA5 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs747206877, COSV59478163; called by muse, mutect2, varscan2
- GANAB | c.2291G>A p.G764D | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs1199675120, COSV99642079; called by muse, mutect2, varscan2
- GARNL3 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs1403355626; called by muse, mutect2, varscan2
- GAS2L2 | c.1226del p.P409Lfs*92 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs782212939; called by mutect2, pindel, varscan2
- GATAD2B | c.1171A>G p.M391V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV100897909; called by muse, mutect2, varscan2
- GFI1B | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs776772049, COSV100254304; called by mutect2, varscan2
- GFPT1 | c.1228A>T p.T410S (on ENST00000357308 / NM_001244710.2; = p.T392S on NM_002056.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV100622883; called by muse, mutect2, varscan2
- GGPS1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs1262402879, COSV99270519; called by muse, mutect2, varscan2
- GGT6 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.04); catalogued as COSV99626416; called by muse, mutect2, varscan2
- GJA5 | c.1022A>C p.K341T | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as COSV99605634; called by muse, mutect2, varscan2
- GLMN | c.263del p.L88* | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs1557567906; called by mutect2, pindel, varscan2
- GLYCTK | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs766827317, COSV99980844; called by muse, mutect2, varscan2
- GNL3 | c.1318A>G p.I440V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.074); catalogued as rs1046647416, COSV99803927; called by muse, mutect2, varscan2
- GOLGA3 | c.2824G>A p.D942N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as rs1164907851, COSV52636472, COSV99210766; called by muse, mutect2, varscan2
- GPN2 | c.254T>C p.M85T | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100658843; called by muse, mutect2, varscan2
- GPR21 | c.948G>T p.K316N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV101016473; called by muse, mutect2, varscan2
- GRAMD1A | c.871-1G>T p.X291_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as COSV58767793; called by muse, mutect2, varscan2
- GRIK1 | c.2822G>A p.R941Q (on ENST00000327783 / NM_001330994.2; = p.R897Q on NM_175611.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs748380852, COSV100583163; called by muse, mutect2, varscan2
- GRIK1 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100516470; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIP1 | c.2044C>G p.P682A (on ENST00000359742 / NM_001379345.1; = p.P630A on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs767751370, COSV99669979; called by muse, mutect2, varscan2
- GSAP | c.1035T>A p.Y345* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99990305; called by muse, mutect2, varscan2
- HAUS7 | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.843); catalogued as rs782321995, COSV57848038, COSV57848209, COSV57851414; called by muse, mutect2, varscan2
- HDAC4 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs373617636; called by muse, mutect2, varscan2
- HDAC5 | c.1378C>A p.L460I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV56822593; called by muse, mutect2, varscan2
- HDGFL1 | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV100014616; called by muse, mutect2, varscan2
- HDLBP | c.1468del p.V490Cfs*23 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as COSV60491864; called by mutect2, pindel, varscan2
- HECA | c.1004del p.G335Dfs*27 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs771658394; called by mutect2, pindel, varscan2
- HERC5 | c.896A>G p.Q299R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99987868; called by muse, mutect2, varscan2
- HIF3A | c.1880G>A p.S627N (on ENST00000377670 / NM_152795.4; = p.S558N on NM_022462.4) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.012); catalogued as COSV99355912; called by muse, mutect2, varscan2
- HIVEP3 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV99913127; called by muse, mutect2, varscan2
- HMCN1 | c.3721T>C p.C1241R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763459200, COSV99631363; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs761272507; called by mutect2, varscan2
- HTR1B | c.73T>G p.L25V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100885438; called by muse, mutect2, varscan2
- HUWE1 | c.10079A>G p.N3360S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99473041; called by muse, mutect2, varscan2
- IFT122 | c.2779G>T p.D927Y (on ENST00000348417 / NM_052989.3; = p.D868Y on NM_018262.4) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV104407267, COSV99959519; called by muse, mutect2, varscan2
- IGFN1 | c.2662A>G p.S888G (on ENST00000295591 / NM_001367841.1; = p.S3345G on NM_001164586.2) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV99812810; called by muse, mutect2, varscan2
- IGHMBP2 | c.2734T>C p.F912L | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99662234; called by muse, mutect2, varscan2
- IGSF10 | c.687G>A p.W229* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99183502; called by muse, mutect2
- IGSF21 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99245431; called by muse, mutect2
- IGSF21 | c.1196T>C p.L399P | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99245433; called by muse, mutect2, varscan2
- IGSF9B | c.439dup p.Q147Pfs*10 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | catalogued as rs748943611; called by mutect2, varscan2
- IL17RD | c.1516C>A p.Q506K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.371); catalogued as COSV99577502; called by muse, mutect2
- IL36RN | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs755465505, COSV100697278; called by muse, mutect2, varscan2
- INPPL1 | c.2927dup p.P977Tfs*7 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs749079348; called by mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- INVS | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs758802357, COSV99317732; called by muse, varscan2
- INVS | c.2840C>T p.A947V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.054); catalogued as COSV52449276; called by muse, mutect2, varscan2
- IQSEC2 | c.3064C>T p.R1022C (on ENST00000642864 / NM_001111125.3; = p.R817C on NM_015075.2) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV64728168; called by muse, mutect2, varscan2
- ISLR2 | c.1157del p.G386Efs*117 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs1417359406; called by mutect2, pindel, varscan2
- ITGAL | c.2474del p.P825Rfs*11 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as COSV100776292; called by mutect2, pindel, varscan2
- ITPRID2 | c.3210+1G>C p.X1070_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as rs777082632, COSV100238449; called by muse, mutect2, varscan2
- ITPRIP | c.457dup p.A153Gfs*18 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | catalogued as rs752551075; called by mutect2, pindel, varscan2
- JMJD1C | c.6075del p.E2026Kfs*45 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs1226801045; called by mutect2, varscan2
- KANSL1 | c.611del p.G204Vfs*2 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | catalogued as rs1304078301; called by mutect2, pindel, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as rs754892524; called by mutect2, varscan2
- KCNB1 | c.2325dup p.K776Qfs*23 | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | catalogued as rs747521886; called by mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs752059864; called by mutect2, varscan2
- KCND1 | c.1664G>A p.S555N | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.038); catalogued as COSV99502043; called by muse, mutect2, varscan2
- KCNK6 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99649395; called by muse, mutect2, varscan2
- KCNS3 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100411287, COSV58407461; called by muse, mutect2, varscan2
- KCTD13 | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV100442173; called by muse, mutect2, varscan2
- KCTD2 | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100483337, COSV100483381; called by muse, mutect2, varscan2
- KDM1B | c.2014T>G p.W672G (on ENST00000449850; = p.W439G on NM_153042.4) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99924398; called by muse, mutect2, varscan2
- KIAA1217 | c.2516C>T p.A839V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV100286860; called by muse, mutect2, varscan2
- KIF12 | c.718C>A p.L240I (on ENST00000640217; = p.L102I on NM_138424.1) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.48); catalogued as COSV100936014; called by muse, mutect2, varscan2
- KIF21A | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs144047911; called by muse, mutect2, varscan2
- KIF6 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99759452; called by muse, mutect2, varscan2
- KL | c.1546G>T p.E516* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV101199126; called by muse, mutect2, varscan2
- KLHL15 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV100044267; called by muse, mutect2, varscan2
- KLHL25 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); catalogued as COSV100563646; called by muse, mutect2
- KLHL32 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV100987389; called by muse, mutect2, varscan2
- KLK15 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs964467613, COSV56827385; called by muse, mutect2, varscan2
- KMT2D | c.14545A>G p.S4849G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56495632; called by muse, mutect2, varscan2
- KNL1 | c.3697T>G p.C1233G (on ENST00000346991 / NM_170589.5; = p.C1207G on NM_144508.5) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs1220560734, COSV100706682; called by mutect2, varscan2
- KRT26 | c.714del p.N239Tfs*2 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs1007245915; called by mutect2, pindel, varscan2
- L3MBTL1 | c.2317T>C p.W773R (on ENST00000418998 / NM_001377303.1; = p.W683R on NM_015478.7) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100917021; called by muse, mutect2, varscan2
- LAMB2 | c.1732-2A>G p.X578_splice | Splice Site (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100565325; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCE2A | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100909179; called by muse, mutect2, varscan2
- LDHB | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs753313189, COSV100636389, COSV100636413; called by muse, mutect2, varscan2
- LDLR | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV99370086; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LGALS9 | c.883C>T p.P295S (on ENST00000395473 / NM_009587.3; = p.P263S on NM_002308.4) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.076); catalogued as COSV100119486; called by muse, mutect2, varscan2
- LHCGR | c.1764dup p.A589Cfs*17 | Frame Shift Ins (INS) | VAF 11/35 reads (31%) | catalogued as rs1293879367; called by mutect2, varscan2
- LILRA4 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV99393228; called by muse, mutect2
- LIMCH1 | c.1513A>G p.T505A | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100574006; called by muse, varscan2
- LINGO1 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1444878510, COSV100796437; called by muse, mutect2, varscan2
- LMO2 | c.133G>A p.A45T (on ENST00000395833 / NM_001142315.2; = p.A114T on NM_005574.4) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs758372857, COSV99137850; called by muse, mutect2, varscan2
- LOXL2 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs560196062, COSV101207808, COSV66693009; called by muse, mutect2, varscan2
- LRAT | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV100312121; called by muse, mutect2, varscan2
- LRBA | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100841830; called by muse, mutect2, varscan2
- LRIG2 | c.225del p.D76Tfs*27 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as rs768751013; called by mutect2, pindel, varscan2
- LRP1B | c.6753A>G p.I2251M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67183150; called by muse, mutect2
- LRRC37A3 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs760812476, COSV100141110; called by muse, mutect2, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- LRRIQ1 | c.1470del p.K490Nfs*28 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as COSV101280733; called by mutect2, varscan2
- LRRK1 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs747828168, COSV52607400; called by muse, mutect2, varscan2
- LRRTM1 | c.740T>G p.I247S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as COSV99702770; called by muse, mutect2, varscan2
- LTBP2 | c.5391G>T p.E1797D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100000560; called by muse, mutect2, varscan2
- LY9 | c.1366T>G p.W456G | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV99626954; called by muse, mutect2
- MAG | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV100727937; called by muse, mutect2
- MAG | c.1297G>A p.V433M | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs146536656, COSV62700097; called by muse, mutect2
- MAP3K12 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99913360; called by muse, mutect2, varscan2
- MAP7D3 | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV100286461; called by muse, mutect2, varscan2
- MAPK7 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs761235886, COSV55191632; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363588188, COSV99571567; called by muse, mutect2, varscan2
- MAPKAPK2 | c.786del p.F263Sfs*13 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs1553432591; called by mutect2, pindel, varscan2
- MARK2 | c.689A>G p.E230G | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59288720; called by muse, mutect2, varscan2
- MAST2 | c.1082A>G p.Q361R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100788426; called by muse, mutect2, varscan2
- MBTPS1 | c.1684C>A p.L562M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.125); catalogued as COSV58572991; called by muse, mutect2, varscan2
- MCM2 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99413247; called by muse, mutect2, varscan2
- MDM1 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.293); catalogued as rs1180512506, COSV57447576; called by muse, mutect2, varscan2
- MED12 | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.165); catalogued as COSV100378707; called by muse, mutect2, varscan2
- MEFV | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.8); catalogued as COSV54821185; called by muse, mutect2, varscan2
- MEGF8 | c.5007del p.T1670Qfs*60 (on ENST00000251268 / NM_001271938.2; = p.T1603Qfs*60 on NM_001410.3) | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | catalogued as COSV99233906; called by mutect2, pindel, varscan2
- METTL4 | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs368748723; called by mutect2, varscan2
- MEX3B | c.1037del p.G346Efs*181 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs1406688622; called by mutect2, pindel, varscan2
- MGA | c.4197G>A p.M1399I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as COSV54955941; called by muse, mutect2, varscan2
- MIOS | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100402920, COSV60767646; called by muse, mutect2, varscan2
- MIOS | c.929A>T p.E310V | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100402853; called by muse, mutect2
- MNDA | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.09); catalogued as COSV100933380, COSV63742215; called by muse, mutect2, varscan2
- MPC2 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99607620; called by muse, mutect2, varscan2
- MPL | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as COSV65245223; called by muse, mutect2, varscan2
- MRPS17 | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV99567858; called by muse, mutect2, varscan2
- MTAP | c.571dup p.A191Gfs*16 | Frame Shift Ins (INS) | VAF 11/49 reads (22%) | catalogued as rs763209709; called by mutect2, pindel, varscan2
- MTERF2 | c.875del p.L292Yfs*8 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | catalogued as rs775448217; called by mutect2, pindel, varscan2
- MTUS2 | c.1840G>T p.G614* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV101462289, COSV101462366; called by muse, mutect2, varscan2
- MUC5B | c.11960G>C p.S3987T | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV101500501; called by muse, mutect2, varscan2
- MUC6 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370422325; called by muse, mutect2, varscan2
- MYBPC3 | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.784); catalogued as rs747965077, COSV99909072; called by muse, mutect2, varscan2
- MYC | c.977A>G p.K326R (on ENST00000377970; = p.K341R on NM_002467.6) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs893110546, COSV99420766; called by muse, mutect2, varscan2
- MYCBPAP | c.1004T>C p.I335T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100088509; called by muse, mutect2, varscan2
- MYH15 | c.5447C>T p.A1816V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV99843676; called by muse, mutect2, varscan2
- MYH4 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99701627; called by muse, mutect2, varscan2
- MYH6 | c.1925del p.K642Rfs*19 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as COSV62449409; called by mutect2, pindel, varscan2
- NAA10 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as rs1391318903, COSV100604103; called by muse, mutect2, varscan2
- NAA20 | c.535T>C p.*179Qext*11 | Nonstop Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100131730; called by muse, mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 7/14 reads (50%) | catalogued as rs763376147; called by mutect2, varscan2
- NCAM2 | c.638T>C p.M213T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV53073243; called by muse, mutect2, varscan2
- NCDN | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100357481; called by muse, mutect2, varscan2
- NCLN | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs560254335, COSV55742730, COSV99860020; called by muse, mutect2, varscan2
- NCOR1 | c.2807T>C p.V936A | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV51990041; called by muse, mutect2, varscan2
- NDRG1 | c.325G>T p.G109W | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100106211; called by muse, mutect2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs747914168; called by mutect2, varscan2
- NEURL1 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV63914014; called by muse, mutect2, varscan2
- NHSL2 | c.605C>A p.P202H (on ENST00000510661; = p.P568H on NM_001013627.2) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101030195; called by muse, mutect2, varscan2
- NLRP13 | c.2662T>C p.S888P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100738343; called by muse, mutect2, varscan2
- NOS3 | c.2069G>A p.G690D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99871861; called by muse, mutect2
- NOTCH2 | c.4509C>T p.C1503= | Splice Region (SNP) | VAF 16/52 reads (31%) | catalogued as COSV56697714, COSV99865126; called by muse, mutect2, varscan2
- NOTCH3 | c.4858C>A p.L1620M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99657827; called by muse, mutect2, varscan2
- NOTCH4 | c.3506G>A p.R1169Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs748069011, COSV66678447; called by muse, mutect2, varscan2
- NPAP1 | c.317del p.P106Rfs*9 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs762821502; called by mutect2, pindel, varscan2
- NPAS4 | c.1742C>A p.P581H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100215088; called by muse, mutect2, varscan2
- NPC1L1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs200554468, COSV99212621; called by muse, mutect2, varscan2
- NPEPL1 | c.1181A>C p.E394A | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100622469; called by muse, mutect2, varscan2
- NPTN | c.619A>G p.K207E | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.91); catalogued as COSV99766571; called by muse, mutect2, varscan2
- NRK | c.1839G>T p.E613D | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99688304; called by muse, mutect2, varscan2
- NRXN1 | c.3499C>T p.R1167* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as rs199546979, COSV58438923, COSV58455553; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NRXN2 | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1452822833, COSV99634863; called by muse, mutect2, varscan2
- NSUN2 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV99243304; called by muse, mutect2, varscan2
- NTRK2 | c.1097A>G p.E366G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV99456592; called by muse, mutect2, varscan2
- NUP160 | c.3719C>T p.T1240M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs535059681, COSV65854418; called by muse, mutect2, varscan2
- NUP210 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1380145119, COSV54408879; called by muse, mutect2
- OAZ2 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs907650084, COSV100386446; called by muse, mutect2, varscan2
- OGFOD2 | c.763G>A p.A255T (on ENST00000228922 / NM_001304833.1; = p.A195T on NM_024623.3) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs376678539; called by muse, mutect2, varscan2
- OPN5 | c.719T>A p.I240N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV99789890; called by muse, mutect2, varscan2
- OR10A7 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV100406603; called by muse, mutect2, varscan2
- OR1C1 | c.164T>A p.L55H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101376246; called by muse, mutect2, varscan2
- OR2B3 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101013813; called by muse, mutect2, varscan2
- OR4X1 | c.515T>C p.M172T | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs1565364119, COSV100186765; called by muse, mutect2, varscan2
- OR51G1 | c.521A>G p.H174R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV58968416, COSV58969989; called by muse, mutect2, varscan2
- OR52B6 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs760768854, COSV100798510; called by muse, mutect2
- OR5B12 | c.527del p.F176Sfs*8 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as COSV56904202; called by mutect2, pindel, varscan2
- OR5M11 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs1418509580, COSV101602051, COSV73141713; called by muse, mutect2, varscan2
- OR8H3 | c.934A>G p.R312G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.717); catalogued as COSV100539040; called by muse, mutect2, varscan2
- OVGP1 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV100868200; called by muse, mutect2
- PADI2 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV100972022; called by muse, mutect2, varscan2
- PAN2 | c.2653G>A p.V885I (on ENST00000425394 / NM_001127460.3; = p.V881I on NM_014871.5) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as rs761334179, COSV57753709; called by muse, mutect2, varscan2
- PAPSS2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760085327, COSV100753594; called by muse, varscan2
- PARD3B | c.3466C>T p.R1156* (on ENST00000406610 / NM_001302769.2; = p.R1087* on NM_057177.7) | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as rs776213727, COSV100594116; called by muse, mutect2, varscan2
- PARP14 | c.3965del p.N1322Ifs*26 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs758945932; called by mutect2, varscan2
- PATJ | c.3226A>C p.N1076H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100334500; called by muse, mutect2, varscan2
- PATZ1 | c.1814A>G p.Y605C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56746011; called by muse, mutect2, varscan2
- PCARE | c.2012C>T p.T671I | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100527671; called by muse, mutect2
- PCDHA9 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 69/93 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs762397793, COSV65324104, COSV65324744; called by muse, mutect2, varscan2
- PCDHGA3 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as COSV99541397; called by muse, mutect2, varscan2
- PCDHGA7 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs867210871, COSV53906024; called by muse, mutect2, varscan2
- PCIF1 | c.821+1G>T p.X274_splice | Splice Site (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100976090; called by muse, mutect2, varscan2
- PCLO | c.11944C>T p.R3982C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61616758, COSV61649758; called by muse, mutect2, varscan2
- PCLO | c.2171C>A p.P724H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV100434152; called by muse, mutect2, varscan2
- PDCD6IP | c.2453C>A p.P818H | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100218921; called by muse, mutect2
- PDHX | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs150518427; called by muse, mutect2, varscan2
- PEG3 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs776749398, COSV55631503; called by muse, mutect2, varscan2
- PEPD | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389880105, COSV99728215; called by muse, mutect2, varscan2
- PHF8 | c.2690G>A p.R897H (on ENST00000357988 / NM_001184896.1; = p.R861H on NM_015107.3) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs910930645, COSV100154456; called by muse, mutect2, varscan2
- PI4KA | c.2816T>C p.V939A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as COSV99747086; called by muse, mutect2, varscan2
- PIGF | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs367591899; called by muse, varscan2
- PITPNM2 | c.1691del p.G564Afs*41 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | catalogued as rs1168761440, COSV99758984; called by mutect2, pindel, varscan2
- PJA1 | c.917G>T p.R306I (on ENST00000361478 / NM_145119.4; = p.R118I on NM_022368.5) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.986); catalogued as COSV100824754; called by muse, mutect2, varscan2
- PKHD1 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs768019626, COSV100584085, COSV61886094; called by muse, mutect2, varscan2
- PLCD1 | c.103T>G p.S35A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); catalogued as COSV100587621; called by muse, mutect2, varscan2
- PLCD3 | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV100504302; called by muse, mutect2, varscan2
- PLEKHA7 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100850318; called by muse, mutect2, varscan2
- PLOD3 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs779308242, COSV99778115; called by muse, mutect2
- PLSCR5 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.76); PolyPhen benign (0.026); catalogued as COSV101494501; called by muse, mutect2, varscan2
- PLXNB1 | c.6115G>A p.A2039T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99602875, COSV99603045; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 5/11 reads (45%) | catalogued as rs782076287; called by mutect2, varscan2
- PMS2 | c.1453A>G p.T485A | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99764355; called by muse, mutect2
- PNPLA7 | c.1337G>T p.R446M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as COSV99481018; called by muse, mutect2, varscan2
- POLE | c.2717C>T p.T906I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100267287; called by muse, mutect2, varscan2
- POLR1A | c.4372A>G p.K1458E | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99807972; called by muse, mutect2, varscan2
- POP1 | c.1195dup p.I399Nfs*4 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | catalogued as rs762132704; called by mutect2, varscan2
- POU4F3 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57944389; called by muse, mutect2, varscan2
- PPP1R9B | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs1240482007, COSV100380752; called by muse, mutect2, varscan2
- PRCC | c.1093A>G p.S365G | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV99618766; called by muse, mutect2, varscan2
- PRKD1 | c.935G>C p.C312S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100120821; called by muse, mutect2, varscan2
- PRLR | c.1529T>C p.V510A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99184504; called by muse, varscan2
- PRNP | c.104del p.G35Afs*75 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV101057283; called by mutect2, pindel, varscan2
- PRRG3 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs367767075, COSV64850968; called by muse, mutect2, varscan2
- PRSS36 | c.1942G>T p.G648C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99191293; called by muse, mutect2, varscan2
- PTBP1 | c.931del p.L311Wfs*57 (on ENST00000349038 / NM_031991.4; = p.L337Wfs*57 on NM_002819.5) | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs1421431048; called by mutect2, pindel, varscan2
- PTGDR | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100035655; called by muse, mutect2, varscan2
- PTGES3 | c.130A>G p.S44G | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV100009735; called by muse, mutect2, varscan2
- PUM2 | c.3004G>A p.V1002M | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339183455, COSV100163781; called by muse, mutect2, varscan2
- PWWP3A | c.241G>A p.A81T (on ENST00000627377; = p.A80T on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.09); catalogued as COSV100262135; called by muse, mutect2, varscan2
- PXDN | c.4358del p.P1453Lfs*8 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as rs1432394931, COSV53245090; called by mutect2, pindel, varscan2
- PXDN | c.1585A>G p.S529G | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.232); catalogued as COSV99414052; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3387del p.A1130Pfs*50 | Frame Shift Del (DEL) | VAF 26/66 reads (39%) | catalogued as rs752866106; called by mutect2, varscan2
- RAB11FIP5 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.273); catalogued as rs764184258, COSV99242177; called by muse, mutect2, varscan2
- RABL2A | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.199); catalogued as COSV64573258; called by muse, mutect2, varscan2
- RAD21 | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52056786, COSV99814634, COSV99815340; called by muse, mutect2, varscan2
- RALGPS2 | c.574A>G p.S192G | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV100244059; called by muse, mutect2
- RANBP9 | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV99163577; called by mutect2, varscan2
- RAPGEF1 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV64700499; called by muse, mutect2, varscan2
- RAPGEF6 | c.3665A>G p.K1222R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.02); catalogued as COSV99726888; called by muse, mutect2, varscan2
- RAVER1 | c.1071del p.K358Sfs*177 (on ENST00000615032; = p.K358Sfs*149 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs773370779, COSV99532335; called by mutect2, pindel, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | catalogued as COSV56484832; called by mutect2, varscan2
- REV1 | c.557T>C p.M186T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99301133; called by muse, mutect2, varscan2
- REXO5 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV99759292; called by muse, mutect2, varscan2
- RFX1 | c.1441G>A p.G481S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54333459; called by muse, mutect2, varscan2
- RHOBTB1 | c.129T>G p.Y43* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100558561; called by muse, mutect2, varscan2
- RHOG | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV99544413; called by muse, mutect2, varscan2
- RIC1 | c.3304G>A p.A1102T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs982268642, COSV52605820; called by muse, mutect2, varscan2
- RIC8A | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.424); catalogued as COSV100254863; called by muse, mutect2, varscan2
- RIMBP2 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs370841973; called by muse, mutect2, varscan2
- RIMS4 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs1428179937, COSV100865154; called by muse, mutect2
- RNF157 | c.1558A>G p.M520V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV99487146; called by muse, mutect2, varscan2
- RNF157 | c.208-3_208-2del p.X70_splice | Splice Site (DEL) | VAF 8/56 reads (14%) | catalogued as rs1414095583; called by pindel, varscan2
- RNF24 | c.143G>T p.R48M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100271011; called by muse, mutect2, varscan2
- RNLS | c.216del p.K72Nfs*10 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | catalogued as rs765347248, CX1212286; called by mutect2, pindel, varscan2
- ROBO2 | c.1436G>T p.R479L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100167830, COSV59898161; called by muse, mutect2, varscan2
- RPAP1 | c.2062G>A p.G688S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs747850058, COSV100427206; called by muse, mutect2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS18 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV101005660; called by muse, mutect2, varscan2
- RRH | c.324del p.F108Lfs*18 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as rs751964437; called by mutect2, varscan2
- RRM2B | c.726A>C p.L242F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV99310256; called by muse, mutect2, varscan2
- RRP12 | c.3508G>T p.G1170C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV100213283; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs759252078; called by mutect2, varscan2
- RXRA | c.911-1G>T p.X304_splice | Splice Site (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100709196; called by muse, mutect2, varscan2
- S100A1 | c.56A>G p.H19R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV99418052; called by muse, mutect2, varscan2
- SAAL1 | c.789G>A p.W263* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100253934; called by muse, mutect2, varscan2
- SAFB2 | c.2471del p.G824Afs*8 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as rs759920279; called by mutect2, pindel, varscan2
- SALL1 | c.1366A>G p.K456E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99174910; called by muse, mutect2, varscan2
- SALL4 | c.2233C>T p.R745C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs111502708; called by muse, mutect2, varscan2
- SAMM50 | c.1229G>C p.G410A | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV100601406; called by muse, mutect2, varscan2
- SCAMP5 | c.317T>C p.M106T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100723839; called by muse, mutect2, varscan2
- SCAPER | c.3078G>A p.T1026= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as rs752094588, COSV57751829; called by muse, mutect2, varscan2
- SCGN | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100618784; called by muse, mutect2, varscan2
- SCN1A | c.4792T>A p.Y1598N (on ENST00000303395 / NM_001202435.3; = p.Y1587N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57679704; called by muse, mutect2, varscan2
- SCN4A | c.2753C>A p.P918H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV101438555; called by muse, mutect2, varscan2
- SCN5A | c.1651G>C p.A551P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as CM056394, COSV100349215; called by muse, mutect2, varscan2
- SEC24A | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV100524577; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 13/22 reads (59%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SECISBP2 | c.2494A>G p.S832G | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs1405873609, COSV100358528; called by muse, mutect2, varscan2
- SEMA6C | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV100501402; called by muse, mutect2, varscan2
- SEMG2 | c.820A>G p.S274G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV101034145; called by mutect2, varscan2
- SETDB1 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99645122; called by muse, mutect2, varscan2
- SETDB1 | c.2468T>A p.I823N | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54990136, COSV99645128; called by muse, mutect2, varscan2
- SEZ6L | c.2866A>G p.N956D | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs1284698473, COSV50663716; called by muse, varscan2
- SH2D4A | c.828_829insA p.L277Ifs*30 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | catalogued as COSV99744872; called by mutect2, pindel, varscan2
- SH3RF1 | c.2306G>T p.R769M | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99499202; called by muse, mutect2, varscan2
- SH3RF2 | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV100767861; called by muse, mutect2, varscan2
- SHD | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs765408203, COSV100010364; called by muse, mutect2, varscan2
- SI | c.2482G>T p.G828* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV52299032; called by muse, mutect2
- SINHCAF | c.218del p.N73Tfs*6 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs771414532; called by mutect2, varscan2
- SLAIN2 | c.504del p.K168Nfs*27 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs769982983; called by mutect2, pindel, varscan2
- SLC11A2 | c.377G>T p.G126V (on ENST00000394904 / NM_001379455.1; = p.G97V on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100014884; called by muse, mutect2, varscan2
- SLC12A1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.946); catalogued as COSV100372425; called by muse, mutect2, varscan2
- SLC16A6 | c.1535del p.N512Mfs*58 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | catalogued as rs35640830; called by mutect2, pindel, varscan2
- SLC22A18 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV100045267; called by muse, mutect2, varscan2
- SLC25A12 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV99785154; called by muse, mutect2, varscan2
- SLC38A10 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569770411, COSV99917638; called by muse, mutect2, varscan2
- SLC43A1 | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as COSV99561086; called by muse, mutect2, varscan2
- SLC43A2 | c.1157A>G p.D386G | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100025088; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as rs759883814, COSV56092392; called by mutect2, pindel, varscan2
- SLC9C2 | c.1414G>C p.V472L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as COSV100876844; called by muse, mutect2, varscan2
- SLFN12 | c.555dup p.D186* | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | catalogued as rs747319777; called by mutect2, varscan2
- SMAGP | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV101199408; called by muse, mutect2, varscan2
- SMARCAD1 | c.1423A>G p.M475V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs765506477, COSV100758971; called by muse, mutect2, varscan2
- SMC2 | c.361A>G p.N121D | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV99659239; called by muse, mutect2, varscan2
- SMPD1 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.21); catalogued as COSV54970975; called by muse, mutect2, varscan2
- SMYD4 | c.1656C>A p.S552R | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV100563105; called by muse, mutect2, varscan2
- SNAPC4 | c.2616G>T p.E872D | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV100047408; called by muse, mutect2, varscan2
- SORBS3 | c.667T>C p.S223P | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1481485531, COSV99531392; called by muse, mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SOX8 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99559302; called by muse, mutect2, varscan2
- SP1 | c.895G>A p.V299I (on ENST00000327443 / NM_138473.3; = p.V292I on NM_003109.1) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV100540721; called by muse, mutect2, varscan2
- SPANXC | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs782653522, COSV62841661; called by muse, mutect2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPHKAP | c.1942A>G p.M648V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100764260; called by muse, mutect2, varscan2
- SPINK5 | c.883-2A>C p.X295_splice | Splice Site (SNP) | VAF 5/56 reads (9%) | catalogued as COSV99806970; called by muse, mutect2
- SPNS2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV100223715; called by muse, mutect2, varscan2
- SREBF2 | c.1184A>G p.K395R | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.989); catalogued as COSV100761464; called by muse, mutect2, varscan2
- SREK1IP1 | c.271del p.R91Gfs*67 | Frame Shift Del (DEL) | VAF 32/44 reads (73%) | catalogued as rs750306056; called by mutect2, varscan2
- SRI | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV99719848; called by muse, mutect2, varscan2
- SRMS | c.925A>G p.N309D | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs748368398, COSV99420653; called by muse, mutect2, varscan2
- SS18L1 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100065068; called by muse, mutect2, varscan2
- SSTR3 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100142735; called by muse, mutect2, varscan2
- ST18 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368972171, COSV99390143; called by muse, mutect2, varscan2
- ST8SIA4 | c.802T>C p.W268R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | PolyPhen possibly damaging (0.651); catalogued as COSV51505285, COSV99185362; called by muse, mutect2, varscan2
- STAG2 | c.1400del p.F467Sfs*3 | Frame Shift Del (DEL) | VAF 30/84 reads (36%) | catalogued as COSV54376603; called by mutect2, varscan2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 38/105 reads (36%) | catalogued as rs746501298; called by mutect2, varscan2
- STAU2 | c.553C>A p.P185T (on ENST00000524300 / NM_001164380.2; = p.P153T on NM_014393.2) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV100869136, COSV100869328; called by muse, mutect2, varscan2
- SULT1A2 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV100187234; called by muse, mutect2, varscan2
- SYCP2L | c.2173A>G p.R725G | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV99305408, COSV99305928; called by muse, mutect2, varscan2
- SYT16 | c.1560del p.R521Dfs*6 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as COSV70859857; called by mutect2, pindel, varscan2
- SYT2 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335871494, COSV100937153; called by muse, mutect2, varscan2
- SYT4 | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV99674031; called by muse, mutect2, varscan2
- TAC4 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.043); catalogued as rs1370809711, COSV100402792; called by muse, mutect2, varscan2
- TALDO1 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs202135397, COSV100032750; called by muse, mutect2, varscan2
- TAS2R14 | c.241dup p.M81Nfs*7 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | catalogued as rs778784911; called by mutect2, pindel, varscan2
- TAS2R46 | c.71A>C p.N24T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101115071; called by muse, mutect2, varscan2
- TBX2 | c.411del p.F138Sfs*17 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as COSV99538794; called by mutect2, pindel, varscan2
- TCTE1 | c.1236G>T p.Q412H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as COSV101025492; called by muse, mutect2, varscan2
- TCTEX1D1 | c.43T>C p.W15R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs772242212, COSV99259238; called by muse, mutect2, varscan2
- TECTA | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773767998, COSV99880377; called by muse, mutect2, varscan2
- TEKT5 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1459589182, COSV51592552; called by muse, mutect2, varscan2
- TENM4 | c.6640C>T p.R2214C | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750150227, COSV53667173; called by muse, mutect2, varscan2
- TESK1 | c.1692G>T p.E564D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99427522; called by muse, mutect2, varscan2
- TET3 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as rs781722716, COSV59881080; called by muse, mutect2, varscan2
- TEX9 | c.1156C>T p.L386F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761132745, COSV99549681; called by muse, varscan2
- TGM2 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs370982887; called by muse, mutect2, varscan2
- THOP1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs796880434, COSV100310645; called by muse, mutect2, varscan2
- THRB | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs549469339, COSV100726165; called by muse, mutect2, varscan2
- THSD7A | c.4127C>T p.A1376V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV101439764; called by muse, mutect2, varscan2
- TMC6 | c.1946G>A p.S649N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100130209, COSV59811991; called by muse, mutect2, varscan2
- TMEM168 | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as rs749776471, COSV100454673; called by muse, mutect2, varscan2
- TMEM25 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100244789; called by muse, mutect2, varscan2
- TMEM50A | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100975942; called by muse, mutect2, varscan2
- TMEM59L | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.557); catalogued as COSV53242433; called by muse, mutect2, varscan2
- TMEM94 | c.3347C>A p.P1116Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050612, COSV58594456; called by muse, mutect2, varscan2
- TMOD3 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1295421680, COSV100419140; called by muse, mutect2, varscan2
- TMTC4 | c.2218G>A p.A740T (on ENST00000376234 / NM_001350577.2; = p.A759T on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100168774; called by muse, mutect2, varscan2
- TMTC4 | c.886C>T p.P296S (on ENST00000376234 / NM_001350577.2; = p.P315S on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60891229; called by muse, mutect2, varscan2
- TNFRSF1A | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as rs104895235, CM023987, COSV99369763; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- TNK1 | c.1874T>C p.I625T (on ENST00000576812 / NM_001251902.2; = p.I620T on NM_003985.5) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.777); catalogued as COSV100247953; called by muse, mutect2, varscan2
- TNNT3 | c.286G>A p.E96K (on ENST00000397301 / NM_001367846.1; = p.E85K on NM_006757.4) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs867571200, COSV53486979; called by muse, mutect2, varscan2
- TNPO2 | c.2373G>T p.Q791H (on ENST00000425528 / NM_001382240.1; = p.Q781H on NM_013433.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs767909855, COSV100790377; called by muse, mutect2, varscan2
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TNXB | c.10757A>G p.H3586R (on ENST00000647633; = p.H3339R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.096); catalogued as COSV100926430; called by muse, mutect2, varscan2
- TOM1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1408644431, COSV101146848; called by muse, mutect2, varscan2
- TOP3A | c.2605G>T p.A869S | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377760887, COSV100329188; called by muse, mutect2, varscan2
- TP63 | c.1157A>G p.Q386R | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as COSV99287555; called by muse, mutect2, varscan2
- TPH2 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as rs773096016, COSV61591462, COSV61593532, COSV61594165; called by muse, mutect2, varscan2
- TPSAB1 | c.109G>C p.A37P | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100127091; called by muse, mutect2, varscan2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs770561785; called by mutect2, varscan2
- TRIM24 | c.1852T>C p.S618P (on ENST00000343526 / NM_015905.3; = p.S584P on NM_003852.4) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100631047; called by muse, mutect2, varscan2
- TRIO | c.4891G>A p.G1631S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.296); catalogued as rs1266639450, COSV60088322; called by muse, mutect2, varscan2
- TRMT6 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV99177583; called by muse, mutect2, varscan2
- TRPC4 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100157175; called by muse, mutect2, varscan2
- TSC22D2 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1209265710, COSV100721242; called by muse, mutect2, varscan2
- TSGA10IP | c.1255C>A p.L419M | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101598413; called by muse, mutect2, varscan2
- TSPAN4 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs369027951; called by muse, mutect2, varscan2
- TSPO2 | c.458G>A p.W153* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV55110135, COSV99770872; called by muse, mutect2, varscan2
- TSPYL1 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.074); catalogued as COSV100889606; called by muse, mutect2, varscan2
- TTF1 | c.1007del p.K336Rfs*87 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs772401251; called by mutect2, varscan2
- TTN | c.2842-1G>T p.X948_splice (on ENST00000591111; = p.X902_splice on NM_003319.4) | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100619206; called by muse, mutect2, varscan2
- UBR4 | c.929T>C p.L310S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.979); catalogued as COSV100921227; called by muse, mutect2
- UBR5 | c.3323C>T p.A1108V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV99641386; called by muse, mutect2, varscan2
- UFM1 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as COSV99522655; called by muse, mutect2, varscan2
- UGT2A1 | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs184187801, COSV54143007; called by muse, mutect2, varscan2
- UNC13D | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as rs778130033, COSV99257039; called by muse, mutect2, varscan2
- UPF2 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); catalogued as rs769626128, COSV100707332; called by muse, mutect2, varscan2
- USH2A | c.4251+2T>C p.X1417_splice | Splice Site (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100237780; called by muse, mutect2, varscan2
- USP11 | c.1783C>T p.R595W (on ENST00000218348; = p.R552W on NM_001371072.1) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99510595; called by muse, mutect2, varscan2
- USP5 | c.2108A>C p.N703T (on ENST00000229268 / NM_001098536.2; = p.N680T on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.098); catalogued as rs1006417106, COSV99978798; called by muse, mutect2, varscan2
- VCAN | c.2876G>A p.S959N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs369644658, COSV99426370; called by muse, mutect2, varscan2
- VEGFB | c.386del p.K129Rfs*5 | Frame Shift Del (DEL) | VAF 23/50 reads (46%) | catalogued as rs747177567, COSV100374813; called by mutect2, varscan2
- VEZT | c.220del p.S74Lfs*38 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs748321397; called by mutect2, varscan2
- VPS13D | c.2129G>C p.R710P | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.451); catalogued as COSV99167377; called by muse, mutect2, varscan2
- VSIR | c.856del p.L286Cfs*51 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs752718137, COSV56484595; called by mutect2, pindel, varscan2
- WASF3 | c.920dup p.P308Afs*29 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | catalogued as rs756173793; called by mutect2, varscan2
- WASL | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV99771737; called by muse, mutect2, varscan2
- WNT1 | c.506dup p.C170Lfs*6 | Frame Shift Ins (INS) | VAF 14/39 reads (36%) | catalogued as rs779969402; called by mutect2, varscan2
- WWC1 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs763380114, COSV54645636; called by muse, mutect2, varscan2
- XPOT | c.1856A>C p.N619T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100225621; called by muse, mutect2, varscan2
- ZBTB1 | c.1147del p.S383Vfs*6 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs747075448, COSV62437585; called by mutect2, varscan2
- ZBTB39 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs966413721, COSV100268101; called by muse, mutect2, varscan2
- ZC3H7B | c.1973A>C p.Q658P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100687479; called by muse, mutect2, varscan2
- ZIC3 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1466996953, COSV99799148; called by muse, mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF134 | c.496G>T p.G166W | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV101270742; called by muse, mutect2, varscan2
- ZNF221 | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99240821; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF41 | c.1559A>G p.E520G | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57442843, COSV57445703; called by muse, mutect2, varscan2
- ZNF585A | c.436A>G p.K146E (on ENST00000292841 / NM_001288800.2; = p.K91E on NM_152655.3) | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.97); PolyPhen benign (0.065); catalogued as COSV99493296; called by muse, mutect2, varscan2
- ZNF668 | c.1543dup p.Q515Pfs*41 | Frame Shift Ins (INS) | VAF 18/71 reads (25%) | catalogued as rs760397907; called by mutect2, varscan2
- ZNF91 | c.3122A>C p.K1041T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100323024; called by muse, mutect2, varscan2
- ZRANB2 | c.684-2A>G p.X228_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99639535; called by muse, varscan2
- ACSL3 | c.1328del p.G443Efs*21 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- ADAM12 | c.696del p.D233Ifs*9 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | called by mutect2, pindel, varscan2
- ADAMTS1 | c.2791del p.R931Efs*3 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- ADCY3 | c.384del p.L129Cfs*19 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- ANK2 | c.4212del p.F1404Lfs*28 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- ARHGAP5 | c.233_234del p.I78Nfs*4 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.3226del p.R1076Gfs*18 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- ARID1A | c.3344del p.P1115Qfs*46 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- ARID1A | c.4555del p.Q1519Rfs*8 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- ATF4 | c.853del p.M285Wfs*36 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- ATP13A5 | c.2097del p.E700Kfs*6 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel
- ATR | c.3764del p.L1255Yfs*7 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- BCAS1 | c.617del p.K206Rfs*38 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- BLK | c.514del p.E172Sfs*2 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- BMS1 | c.1847dup p.L617Afs*20 | Frame Shift Ins (INS) | VAF 8/18 reads (44%) | called by mutect2, pindel, varscan2
- BTAF1 | c.3437del p.L1146Wfs*27 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- BTBD7 | c.2686_2687del p.E896Ifs*7 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- C6 | c.926dup p.D310Gfs*3 | Frame Shift Ins (INS) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- CCDC47 | c.1312del p.R438Efs*8 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | called by mutect2, pindel, varscan2
- CDR1 | c.335del p.L112Wfs*4 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- CENPE | c.6860dup p.N2287Kfs*8 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- CFAP44 | c.609del p.S205Vfs*13 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- CFP | c.967del p.E323Sfs*10 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- CHAD | c.929del p.G310Afs*58 (on ENST00000258969; = p.G310Afs*86 on NM_001267.3) | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- CHD7 | c.1953del p.D652Tfs*59 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- CLMN | c.2602del p.R868Gfs*7 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- COLQ | c.960del p.F320Lfs*12 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- CSPP1 | c.1774_1776del p.P592del (on ENST00000676605; = p.P551del on NM_024790.6) | In Frame Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- DLL1 | c.1756del p.E586Rfs*5 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel
- DNAH11 | c.6480dup p.E2161* | Frame Shift Ins (INS) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- DNAJC1 | c.1258del p.V420Wfs*54 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, varscan2
- DNM1 | c.1571del p.G524Afs*3 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- DRP2 | c.2710del p.R904Gfs*46 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- DSG1 | c.580del p.I194* | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- DUOX1 | c.2673del p.S892Pfs*24 | Frame Shift Del (DEL) | VAF 24/83 reads (29%) | called by mutect2, pindel, varscan2
- EDRF1 | c.1183del p.S395Lfs*5 (on ENST00000356792 / NM_001202438.2; = p.S361Lfs*5 on NM_015608.2) | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- EIF2A | c.1609del p.I537Sfs*4 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- ELOA2 | c.858del p.Q287Kfs*34 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- ENPP2 | c.1248del p.K416Nfs*10 (on ENST00000075322 / NM_001040092.3; = p.K468Nfs*10 on NM_006209.5) | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- EP300 | c.6970del p.H2324Tfs*29 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 34/79 reads (43%) | called by mutect2, pindel, varscan2
- FAAH | c.659del p.G220Vfs*15 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- FANCA | c.784dup p.M262Nfs*7 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- FBXO34 | c.1454del p.L485Cfs*13 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, varscan2
- FCN2 | c.341dup p.L115Pfs*20 | Frame Shift Ins (INS) | VAF 30/109 reads (28%) | called by mutect2, pindel, varscan2
- FOXP1 | c.1240del p.L414* | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, pindel, varscan2
- FSTL5 | c.355dup p.C119Lfs*13 | Frame Shift Ins (INS) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- GLI3 | c.3098del p.P1033Rfs*46 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- GPR161 | c.358dup p.V120Gfs*53 | Frame Shift Ins (INS) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- GPR52 | c.534del p.F178Lfs*60 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- GTF3C1 | c.3820del p.V1274Cfs*14 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- HSPH1 | c.1375del p.I459* | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- IDO1 | c.580dup p.D194Gfs*57 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- ITGB3BP | c.435dup p.V146Sfs*3 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, varscan2
- JAK1 | c.1099del p.S367Lfs*10 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- LCT | c.2513del p.F838Sfs*5 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- MACC1 | c.1639del p.T547Hfs*2 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- MAL2 | c.353del p.L118Yfs*18 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- MAP3K10 | c.1511del p.P504Lfs*10 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | called by mutect2, pindel, varscan2
- MAP4K1 | c.1681del p.H561Tfs*80 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- MIS18BP1 | c.1764dup p.E589Rfs*3 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- MMP13 | c.420dup p.A141Sfs*22 | Frame Shift Ins (INS) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- MOCS2 | c.502-3del | Splice Region (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- MORC2 | c.1379dup p.I461Nfs*7 (on ENST00000397641 / NM_001303256.3; = p.I399Nfs*7 on NM_014941.3) | Frame Shift Ins (INS) | VAF 17/63 reads (27%) | called by mutect2, pindel, varscan2
- MRC1 | c.3604G>A p.A1202T | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- MRC2 | c.3656del p.G1219Afs*5 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- MROH1 | c.1371del p.K458Rfs*23 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- MRPS33 | c.313del p.R105Gfs*51 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- MTA1 | c.1913del p.G638Afs*11 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- MTUS1 | c.1787del p.N596Mfs*13 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- MYRF | c.2314dup p.L772Pfs*30 (on ENST00000278836 / NM_001127392.3; = p.L763Pfs*30 on NM_013279.4) | Frame Shift Ins (INS) | VAF 30/84 reads (36%) | called by mutect2, pindel, varscan2
- NAV1 | c.3868del p.H1290Tfs*30 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- NDNF | c.120del p.H41Mfs*5 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- NLRC5 | c.2815dup p.T939Nfs*24 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- NOX5 | c.1407del p.H470Tfs*10 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- OBSCN | c.19501del p.L6501Yfs*19 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by mutect2, varscan2
- OR51A4 | c.698del p.K233Rfs*17 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | called by mutect2, pindel, varscan2
- PARS2 | c.647del p.P216Qfs*22 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- PDIA3 | c.679dup p.M227Nfs*7 | Frame Shift Ins (INS) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- PDS5B | c.3585del p.S1198Vfs*10 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- PER1 | c.2071del p.A691Pfs*13 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- PHF14 | c.546del p.K182Nfs*19 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- PITPNM1 | c.2457del p.S820Afs*59 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | called by mutect2, pindel, varscan2
- PLD1 | c.2023del p.R675Gfs*33 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | called by mutect2, pindel, varscan2
- PLXNA3 | c.2468del p.P823Rfs*8 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- PNPLA1 | c.488del p.P163Rfs*6 (on ENST00000394571 / NM_001374623.1; = p.P68Rfs*6 on NM_173676.2) | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- PPARA | c.1198dup p.M400Nfs*105 | Frame Shift Ins (INS) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- PPP1R36 | c.563dup p.L188Ffs*5 | Frame Shift Ins (INS) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- PPP1R3F | c.1290dup p.R431Qfs*34 | Frame Shift Ins (INS) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.825del p.K275Nfs*2 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.1075T>C p.C359R | Missense Mutation (SNP) | VAF 92/335 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRAMEF20 | c.424A>G p.R142G | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- R3HDM2 | c.2729del p.G910Vfs*44 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- RAI1 | c.2396del p.P799Lfs*20 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- RBL1 | c.306del p.F102Lfs*4 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
- RFX4 | c.2048del p.T683Sfs*23 (on ENST00000392842 / NM_213594.3; = p.T589Sfs*23 on NM_032491.6) | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- RGS8 | c.186_187del p.H63* (on ENST00000367556 / NM_001369564.2; = p.H81* on NM_033345.3) | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by pindel, varscan2
- RIPPLY3 | c.449del p.G150Efs*72 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- ROCK2 | c.1438del p.T480Qfs*5 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- RYK | c.994_995dup p.I333Gfs*2 (on ENST00000620660 / NM_001005861.2; = p.I330Gfs*2 on NM_002958.4) | Frame Shift Ins (INS) | VAF 16/44 reads (36%) | called by mutect2, varscan2
- SCRIB | c.2089del p.A697Pfs*20 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | called by mutect2, pindel, varscan2
292 further variants in this file (32 protein-altering or splice-affecting, 225 silent, 35 other) are not listed here.
